Somatic mutation profile of tumor specimen 17d55745-4ab3-4a80-a182-af938b (aliquot 17d55745-4ab3-4a80-a182-af938b_D6) from CPTAC case 01BR001, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.0 years (20,074 days).
Specimen 17d55745-4ab3-4a80-a182-af938b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b06a062a-77ea-4230-802f-6f5d96e1a298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 60439729-0ee4-431a-a8db-3325a2 (Blood Derived Normal), aliquot 60439729-0ee4-431a-a8db-3325a2_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da12f820-9319-429e-9cd6-5491cb0b5c1d

The open-access MAF lists 68 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 6, Frame Shift Del 3, Splice Site 3, 3'UTR 2, RNA 2, 3'Flank 1, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1177C>T p.R393* (on ENST00000281708 / NM_001349798.2; = p.R313* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | hotspot (GDC flag); catalogued as COSV55892695; called by muse, mutect2, varscan2
- TP53 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 205/450 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ALDH1L1 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs557729538; called by muse, mutect2, varscan2
- ALDH8A1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs200199318; called by muse, mutect2, varscan2
- AREG | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52645245; called by muse, mutect2
- ARHGEF18 | c.3140C>T p.S1047L (on ENST00000359920 / NM_001130955.2; = p.S943L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs1446018186; called by muse, mutect2, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2
- CHD9 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1408452580; called by muse, mutect2, varscan2
- FLT1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 142/461 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1161996687, COSV56724342; called by muse, mutect2, varscan2
- GRAP | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765807135; called by muse, mutect2, varscan2
- GRM4 | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 94/369 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV65214045; called by muse, mutect2, varscan2
- OSBPL3 | c.1858A>G p.K620E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs889460861; called by muse, mutect2, varscan2
- PHLDB2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs534767460, COSV67312589; called by muse, mutect2, varscan2
- PIK3CD | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 155/740 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63128827; called by muse, mutect2, varscan2
- PPFIA1 | c.2384A>T p.H795L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV99557117; called by muse, mutect2
- PSMC5 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56741528; called by muse, mutect2, varscan2
- PSMD7 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs373688812; called by muse, mutect2, varscan2
- RNF148 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs376463521; called by muse, mutect2, varscan2
- SLC13A4 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1224064736, COSV58528453; called by muse, mutect2, varscan2
- TAS2R40 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as rs1345932604; called by muse, mutect2, varscan2
- TENM4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.974); catalogued as COSV99570406; called by muse, mutect2, varscan2
- TIGD4 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100427961; called by muse, mutect2, varscan2
- TRAPPC1 | c.419_421del p.F140del | In Frame Del (DEL) | VAF 24/206 reads (12%) | catalogued as rs780009126; called by pindel, varscan2
- TRIP6 | c.1019C>A p.A340D | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV52341032; called by muse, mutect2, varscan2
- BAZ1A | c.2998-1G>A p.X1000_splice | Splice Site (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- BCHE | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by mutect2, varscan2
- CCDC136 | c.3173G>A p.C1058Y | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC66 | c.1843+7G>A | Splice Region (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- CDH9 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 183/528 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP170B | c.4162C>A p.P1388T (on ENST00000453495; = p.P1317T on NM_015005.3) | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CSPP1 | c.1395+2T>C p.X465_splice (on ENST00000676605; = p.X424_splice on NM_024790.6) | Splice Site (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- EIF5A | c.428_429del p.E143Gfs*53 | Frame Shift Del (DEL) | VAF 38/318 reads (12%) | called by pindel, varscan2
- GCNT4 | c.1300_1301del p.D434Lfs*13 | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | called by pindel, varscan2
- HECW2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- MFSD3 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MYBPC1 | c.1957+2T>C p.X653_splice (on ENST00000550270 / NM_206820.2; = p.X678_splice on NM_002465.4) | Splice Site (SNP) | VAF 34/229 reads (15%) | called by muse, mutect2, varscan2
- PLEC | c.11195T>G p.L3732R (on ENST00000322810 / NM_201380.4; = p.L3622R on NM_000445.5) | Missense Mutation (SNP) | VAF 129/1265 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SCLT1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA7A | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.741); called by muse, mutect2
- SP2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMED6 | c.656_660del p.Q219Lfs*23 | Frame Shift Del (DEL) | VAF 60/338 reads (18%) | called by mutect2, pindel*, varscan2*
- UTP14C | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- VMO1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ADAM15 | c.315T>C p.T105= | Silent (SNP) | VAF 21/326 reads (6%) | called by muse, mutect2
- AP2A1 | c.675C>T p.C225= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs368089270; called by muse, mutect2, varscan2
- CA14 | c.1008G>A p.E336= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as rs1553849030; called by muse, mutect2
- CCDC105 | c.6C>T p.R2= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- FZD7 | c.1458G>A p.L486= | Silent (SNP) | VAF 122/352 reads (35%) | called by muse, mutect2, varscan2
- GLRA2 | c.1200G>A p.P400= | Silent (SNP) | VAF 33/292 reads (11%) | catalogued as rs780981846, COSV54341759; called by muse, mutect2, varscan2
- GPR146 | c.90G>A p.S30= | Silent (SNP) | VAF 97/348 reads (28%) | catalogued as rs770106886, COSV52465478; called by muse, mutect2, varscan2
- MCF2L | c.2877G>A p.A959= (on ENST00000375608; = p.A927= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/301 reads (10%) | catalogued as rs375138776; called by muse, mutect2, varscan2
- OR11H12 | c.156G>A p.L52= | Silent (SNP) | VAF 15/358 reads (4%) | called by muse, mutect2
- PCDH9 | c.123A>G p.G41= | Silent (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- SVIL | c.5193C>T p.N1731= (on ENST00000355867 / NM_021738.3; = p.N1305= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/625 reads (8%) | catalogued as rs760014574; called by muse, mutect2
- TBC1D19 | c.1326C>T p.R442= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV53521957; called by muse, mutect2, varscan2
- TUBB6 | c.690C>T p.S230= | Silent (SNP) | VAF 72/1187 reads (6%) | catalogued as COSV99302149; called by muse, mutect2
- AC135782.1 | n.438G>T | RNA (SNP) | VAF 73/283 reads (26%) | called by muse, mutect2, varscan2
- AK2 | chr1:33008139 T>C | 3'Flank (SNP) | VAF 42/806 reads (5%) | called by muse, mutect2
- AOPEP | c.1978-948T>A | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- BOD1P2 | n.112G>A | RNA (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- ERCC2 | c.183+31A>G | Intron (SNP) | VAF 162/586 reads (28%) | called by muse, mutect2, varscan2
- FARP2 | c.1411+196G>A | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs754118668, COSV99885594; called by mutect2, varscan2
- FMC1 | c.*1A>G | 3'UTR (SNP) | VAF 18/100 reads (18%) | catalogued as rs1038754404; called by muse, mutect2, varscan2
- JRK | c.*5451A>T | 3'UTR (SNP) | VAF 32/390 reads (8%) | called by muse, mutect2
- LINC02337 | n.40-15651G>T | Intron (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- MCM7 | c.1848+360G>C | Intron (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- UCKL1 | c.924-164G>A | Intron (SNP) | VAF 9/83 reads (11%) | catalogued as rs1354729399; called by muse, mutect2, varscan2
- USP53 | chr4:119212402 C>T | 5'Flank (SNP) | VAF 38/309 reads (12%) | catalogued as rs1218374302; called by muse, mutect2, varscan2
